Gene-level copy-number profile of tumor specimen TCGA-02-0446-01A from TCGA case TCGA-02-0446, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 61.7 years (22,541 days).
Specimen TCGA-02-0446-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.e8e618d4-4446-4cc0-9476-a1b990c7e165.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,052 have no estimate.
https://portal.gdc.cancer.gov/files/268a6415-ed0c-4b36-86c1-cda8c823d598

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 45; copy number 1: 5,916; copy number 2: 46,521; copy number 3: 3,036; copy number 12: 7; copy number 13: 46.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-02-0446-01): tumor purity 0.66, ploidy 1.96, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 45 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:50,437,028–50,960,267, 1 gene (within-gene range 0–2): FAF1.
- chr1:50,582,404–50,974,634, 4 genes: RNU6-1026P, PHBP12, MRPS6P2, CDKN2C.
- chr9:21,304,326–22,824,213, 38 genes: IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239.
- chr9:22,747,700–22,768,316, 2 genes: CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 53 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:52,872,982–53,366,066, 1 gene, copy number 12 (within-gene range 2–12): SCFD2.
- chr4:53,265,461–53,460,862, 2 genes, copy number 12: RNU6-310P, FIP1L1.
- chr4:53,459,301–53,701,405, 4 genes, copy number 12 (within-gene range 2–12): LNX1, LNX1-AS1, AC095040.1, LNX1-AS2.
- chr4:56,049,073–58,565,212, 46 genes, copy number 13: CRACD, RNA5SP161, RNU6-197P, AC022267.1, MRPL22P1, AASDH, RPL7AP31, AC068620.1, PPAT, AC068620.2, AC068620.3, PAICS, SRP72, ARL9, THEGL, GLDCP1, HOPX, AC108215.1, RPL17P20, AC022483.1, RN7SL492P, RN7SL357P, SPINK2, Metazoa_SRP, Y_RNA, REST, AC069307.1, NOA1, POLR2B, RNU6-998P, IGFBP7, UBE2CP3, IGFBP7-AS1, AC111197.1, AC105390.1, RPS26P24, LINC02380, AC013724.1, AC107396.1, AC093725.2, AC093725.1, AC104790.1, SRIP1, AC096725.1, LINC02494, AC019133.1.

Autosomal genes at a single copy (total copy number 1): 5,916. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
